Somatic mutation profile of tumor specimen 0DVCFI from CCDI case PBCMJT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 10.0 years (3,662 days).
Specimen 0DVCFI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33ed1288-a30b-4998-a78d-b751bfda05ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVCFT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b440d90-ba91-4462-9aa8-5718244eabf5

The open-access MAF lists 10 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 5, Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C1orf216 | c.103T>C p.F35L | Missense Mutation (SNP) | VAF 245/550 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs950222824; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1117G>C p.A373P | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1348789502; called by muse, mutect2
- USP47 | c.2518A>G p.T840A (on ENST00000399455 / NM_001372095.1; = p.T752A on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/579 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- ZNF200 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 36/532 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2
- DSCAM | c.597G>A p.T199= | Silent (SNP) | VAF 139/381 reads (36%) | catalogued as rs374370618; called by muse, mutect2, varscan2
- HTR1B | c.1059C>T p.F353= | Silent (SNP) | VAF 180/629 reads (29%) | catalogued as rs201701788; called by muse, mutect2, varscan2
- IGSF1 | c.1896C>T p.I632= | Silent (SNP) | VAF 48/554 reads (9%) | catalogued as rs772551917, COSV63836157; called by muse, mutect2
- IQCH | c.1731C>T p.S577= | Silent (SNP) | VAF 42/279 reads (15%) | catalogued as rs148305719, COSV60053945; called by muse, mutect2, varscan2
- TAAR9 | c.1005G>A p.S335= | Silent (SNP) | VAF 137/595 reads (23%) | catalogued as rs370306299, COSV71512218; called by muse, mutect2, varscan2
- ZYX | c.408+34C>T | Intron (SNP) | VAF 17/232 reads (7%) | called by muse, mutect2
